TARGET case TARGET-30-PAIXNC — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3a51f1c0-710b-5506-ad12-df2efa2ff51a

Demographics
Sex at birth: male; Race: white; Age at index: 1 years; Vital status: Dead; Days to death: 607 days (1.7 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 2.0 years (723 days); Year of diagnosis: 2000; Days to last follow up: 607 days (1.7 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Treatment given: Protocol identifier: 9047.

Follow-up (1 entry)
- Days to follow up: 607 days (1.7 years); Days to first event: 607 days (1.7 years); First event: Death; Year of follow up: 2002.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAIXNC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAIXNC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 607
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.13
- Histology: Unfavorable
- ICDO Description: ABDOMEN/PERITONEUM OR RETROPERITONEUM
